Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72J, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72J-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma, renal cell
Chromophobe 8317/3
Site @ Kidney NOS
C64.9
QW 8/9/13

Diagnosis:

Kidney, left, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, chromophobe type

Sarcomatoid features: not identified

Histologic grade (if applicable): 3 (of 4, Fuhrman classification)

Tumor size (greatest dimension): 5.1 cm

Tumor focality: unifocal

Extent of invasion:

Extra-capsular invasion into perinephric adipose tissue: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Surgical margins:

Renal parenchymal margin: negative but close (1 mm to blue in A6)

Renal capsular margin: not involved

Perinephric adipose tissue margin: not involved

Adrenal gland: not received

Lymph nodes: none received

Other significant findings: none

AJCC Staging: pT1b pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with a left renal mass.

[page 2 of 2]
Gross Description:

Received is one appropriately labeled container, additionally labeled "left renal mass partial nephrectomy." It holds a 35 gram, 5.2 x 4.7 x 3.4 cm partial nephrectomy with a small amount of attached perinephric fat overlying the capsule. The parenchyma is marked blue and the perinephric fat is inked black. The specimen is sectioned to reveal a 5.1 x 3.4 x 2.2 cm solid, variegated, orange/yellow/tan cortical nodule which focally abuts the blue inked parenchymal margin and expands, but does not grossly breach the capsule. The adjacent renal parenchyma is compressed and grossly unremarkable. The perinephric fat is grossly unremarkable.

Block summary:

- A1 - tumor and blue inked parenchymal margin
- A2 - tumor and perinephric fat
- A3 - tumor expanding capsule
- A4-A6 - representative central sections of tumor

Tumor has been given to Tissue Procurement.

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections show a unifocal mass with solid sheets of eosinophilic and clear cells with focal punched-out perinuclear clearing. The differential includes clear cell carcinoma and eosinophilic variant of chromophobe carcinoma. To clarify lineage, immunostains were performed, and show reactivity for CK7, with no reactivity for c-Kit or RCC. This immunophenotype supports a diagnosis of chromophobe carcinoma, and makes renal cell carcinoma unlikely. Dr. concurs.

Histology Discrepancy		☒

Source: NCI Genomic Data Commons file eec7909c-04b8-4933-8477-fd3c9498ad6f (TCGA-UW-A72J.B709D0A0-2567-4FB3-BF52-54444D0C7392.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).